Somatic mutation profile of tumor specimen TCGA-CS-5395-01A (aliquot TCGA-CS-5395-01A-01D-1468-08) from TCGA case TCGA-CS-5395, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G2; Age at diagnosis: 43.4 years (15,848 days).
Specimen TCGA-CS-5395-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f4cc9841-4a00-41ef-987d-598c62e3b087.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-5395-10A (Blood Derived Normal), aliquot TCGA-CS-5395-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9e223e0-1c3d-4449-8f1b-f45fa31ac597

The open-access MAF lists 40 somatic variants for this specimen: 35 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 31, Silent 5, Nonsense Mutation 2, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 80/138 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs121913293, CM074467, COSV64288569, COSV64310838; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 78/210 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM7 | c.1169T>G p.M390R | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV51540157; called by muse, mutect2, varscan2
- ANKEF1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 47/154 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747069695, COSV65692449; called by muse, mutect2, varscan2
- ATP10B | c.3551G>T p.G1184V | Missense Mutation (SNP) | VAF 229/550 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59146838, COSV59152103; called by muse, mutect2, varscan2
- CALN1 | c.586G>A p.A196T (on ENST00000329008 / NM_001017440.3; = p.A238T on NM_031468.4) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770151080, COSV61117552; called by muse, mutect2, varscan2
- CARD14 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs754219698, COSV60123584; called by muse, mutect2, varscan2
- COL6A3 | c.7832C>T p.A2611V | Missense Mutation (SNP) | VAF 100/263 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs114806654, COSV55080355, COSV55089770, COSV55094724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DDR2 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV63371103; called by muse, mutect2, varscan2
- FER1L6 | c.4390A>T p.I1464L | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV67549968; called by muse, mutect2, varscan2
- HIF3A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.091); catalogued as COSV52198624; called by mutect2, varscan2
- LAMA1 | c.7457T>C p.I2486T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV67537170; called by muse, mutect2, varscan2
- LRRC8E | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); catalogued as rs558407711, COSV60718164; called by muse, mutect2, varscan2
- MAP3K19 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 50/120 reads (42%) | catalogued as rs751721304, COSV59637434; called by muse, mutect2
- NUP160 | c.3719C>T p.T1240M | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs535059681, COSV65854418; called by muse, mutect2, varscan2
- OBSCN | c.3194T>C p.L1065P | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52774688; called by muse, mutect2, varscan2
- OR13C2 | c.431T>G p.M144R | Missense Mutation (SNP) | VAF 43/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV73377704; called by muse, varscan2
- OR13C5 | c.431T>G p.M144R | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66164608; called by muse, mutect2
- PCSK2 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 120/458 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs748165327, COSV52732768; called by muse, mutect2, varscan2
- PDE6B | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs369995075; called by muse, mutect2, varscan2
- PKHD1 | c.9127G>T p.V3043L | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.093); catalogued as COSV61875876; called by muse, mutect2, varscan2
- PKHD1 | c.3541G>T p.V1181F | Missense Mutation (SNP) | VAF 136/376 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.178); catalogued as COSV61875890; called by muse, mutect2, varscan2
- RGN | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs960690657, COSV60276177; called by muse, mutect2, varscan2
- SIPA1L1 | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1307638782, COSV62170256; called by muse, mutect2, varscan2
- SPATA31A3 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.515); catalogued as rs984693509; called by mutect2, varscan2
- SUPT16H | c.2942G>A p.G981D | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.992); catalogued as COSV52850180; called by muse, mutect2, varscan2
- SVEP1 | c.3689C>G p.T1230R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs762155273, COSV57036198; called by muse, mutect2, varscan2
- SZT2 | c.2176G>A p.V726M | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs200614334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TENM1 | c.3217G>A p.A1073T | Missense Mutation (SNP) | VAF 126/156 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778994121, COSV64432201, COSV64439008; called by muse, mutect2, varscan2
- TRIP13 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs754712257, COSV51319602; called by muse, mutect2, varscan2
- TRPM6 | c.4079C>A p.T1360N | Missense Mutation (SNP) | VAF 113/292 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as COSV62510456; called by muse, mutect2, varscan2
- USP24 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 23/106 reads (22%) | catalogued as COSV53767771; called by muse, mutect2, varscan2
- ZNF229 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.862); catalogued as rs753505537, COSV52161973; called by muse, mutect2, varscan2
- PLCG1 | c.3494_3495insAGAAGA p.E1163_E1164dup | In Frame Ins (INS) | VAF 75/262 reads (29%) | called by mutect2, pindel, varscan2
- SLC30A6 | c.665+1del p.X222_splice | Splice Site (DEL) | VAF 41/142 reads (29%) | called by mutect2, pindel, varscan2
- CD1A | c.789C>T p.R263= | Silent (SNP) | VAF 72/181 reads (40%) | catalogued as rs376991873; called by muse, mutect2, varscan2
- COL19A1 | c.2115G>A p.G705= | Silent (SNP) | VAF 43/99 reads (43%) | catalogued as COSV59573531; called by muse, mutect2, varscan2
- EDNRA | c.351G>T p.A117= | Silent (SNP) | VAF 77/177 reads (44%) | catalogued as COSV60097590; called by muse, mutect2, varscan2
- SEMA3F | c.2157C>T p.G719= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs758070625, COSV50029752; called by muse, mutect2, varscan2
- TMEM170A | c.369A>C p.T123= | Silent (SNP) | VAF 71/195 reads (36%) | catalogued as COSV62923130; called by muse, mutect2, varscan2
